Somatic mutation profile of tumor specimen TCGA-3T-AA9L-01A (aliquot TCGA-3T-AA9L-01A-11D-A423-09) from TCGA case TCGA-3T-AA9L, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymoma, type B1, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 31.8 years (11,610 days).
Specimen TCGA-3T-AA9L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 04324bc0-f2ac-4af8-b8b5-f4f2f7d1830d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3T-AA9L-10A (Blood Derived Normal), aliquot TCGA-3T-AA9L-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4677cb6f-7447-489c-9ac8-b49df9d5a1bd

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Frame Shift Del 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARSI | c.1670del p.F557Sfs*8 | Frame Shift Del (DEL) | VAF 4/41 reads (10%) | catalogued as rs1323444659; called by mutect2, pindel, varscan2
- ZNF764 | c.409C>T p.P137S | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.04); called by muse, mutect2
